Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3C3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3C3-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS

Patient ID -

(A) LEFT SUPERFICIAL INGUINAL LYMPH NODES, EXCISION:

MELANOMA, METASTATIC TO AT LEAST ONE OF ONE LYMPH NODE (1/1, MATTED LYMPH NODES ARE POSSIBLE).

Largest tumor deposit size: 70 x 65 mm (per gross assessment)

Location: Subcapsular and intraparenchymal

EXTRACAPSULAR EXTENSION: PRESENT.

Skin and subcutis with no pathological findings.

(B) LEFT ILIAC AND OBTURATOR NODES, EXCISION:

MELANOMA, METASTATIC TO FIVE OF TEN LYMPH NODES (5/10)

Largest tumor deposit size: 60 x 50 mm (per gross assessment).

Location: Subcapsular and intraparenchymal

EXTRACAPSULAR EXTENSION: PRESENT

See comment.

(C) LEFT COMMON ILIAC NODES, EXCISION:

MELANOMA, METASTATIC TO TWO OF FIVE LYMPH NODES (2/5).

Largest tumor deposit size: 10 x 8 mm.

Location: Subcapsular and intraparenchymal

Extracapsular extension: not identified

ICD-0-3

Melanoma, Nos 8720/3
Site: lymph node, inguinal
C77.4

10/3/11

COMMENT

(B) Examination of an immunohistochemical study on paraffin sections with an anti-melanocytic cocktail (HMB45, anti-MART1 and anti-tyrosinase) performed on section B5 shows the tumor cells to be positive, supporting the above diagnoses.

GROSS DESCRIPTION

(A) LEFT SUPERFICIAL INGUINAL LYMPH NODES – An unoriented ellipse of skin with attached subcutaneous tissue measuring 28 x 5.5 x 7.0 cm in thickness. A second separate portion of adipose tissue measures 8.0 x 2.5 x 1.5 cm.

The skin surface is free of lesions. The subcutaneous tissue contains a large distorted lymph node or matted lymph node which are entirely replaced by gray-tan fleshy tissue measuring overall 7.0 x 6.5 x 4.5 cm. No additional lesions are identified. Portions of the lymph node tumor are submitted for research purposes. The tumor appears to extend within 0.2 cm of the closest tissue edge.

INK CODE: Blue – peripheral and deep edges.

SECTION CODE: A1, A2, skin tips; A3-A4, tumor with nearest inked surface; A5-A8, additional sections of tumor; A9, representative skin; A10, representative sections, smaller portion of tissue.

(B) LEFT ILIAC AND OBTURATOR NODES – The specimen consists of a portion of fibroadipose tissue with lymph nodes, 12.5 x 7.5 x 2.5 cm. The specimen consists of numerous, greater than ten possible lymph nodes with three very large lymph nodes, largest lymph node #1 is 7.0 x 2.5 x 2.0 cm. Large lymph node #2 is 6.0 x 5.0 x 2.0 cm and large lymph node #3 is 4.0 x 3.0 x 1.8 cm. The remainder of the lymph nodes range in size from 2.0 to 0.1 cm in greatest dimension. The lymph nodes are submitted as follows.

SECTION CODE: B1, one lymph node bisected; B2, one possible lymph node; B3, four possible lymph nodes; B4-B6, one possible lymph node, one per cassette; B7-B9, representative sections of grossly positive lymph node #1; B10-B13, representative sections of grossly positive lymph node #2; B14-B16, representative sections of grossly positive lymph node #3.

(C) LEFT COMMON ILIAC NODES – A portion of fibroadipose tissue (3.5 x 3.0 x 1.0 cm) which contains multiple candidate lymph nodes (up to 1.5 cm in greatest extent). All lymph nodes are entirely submitted.

SECTION CODE: C1, three lymph nodes; C2, one lymph node bisected; C3, one lymph node bisected.

CLINICAL HISTORY

[page 2 of 2]
Melanoma

SNOMED CODES

T-C4810, T-C4600, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Entire report and diagnosis completed by: '

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 7869b1fb-dfb6-4ec5-99be-973380e0f304 (TCGA-D3-A3C3.17FA69D3-C9F6-4B26-BD22-CEB331C8A153.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).